FM case AD3344 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Other and unspecified urinary organs.
https://portal.gdc.cancer.gov/cases/76002efc-0572-46b6-841e-0a4bfff74a00

Male, 55.1 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the urethra; primary biopsied or resected from the urethra. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
